Gene-level copy-number profile of tumor specimen TCGA-V1-A9ZG-01A from TCGA case TCGA-V1-A9ZG, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9ZG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.0341d7ed-3682-45ad-b446-ac589cfe6c4d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-V1-A9ZG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7345c5fb-03a6-45fd-9be3-144688d8040c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 4,104; copy number 2: 55,554; copy number 4: 81; copy number 5: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-V1-A9ZG-01A-11D-A41J-01): tumor purity 0.4, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 59 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,201,647–87,342,612, 1 gene (within-gene range 0–1): NUTM2A-AS1.
- chr10:87,341,685–88,585,733, 26 genes: LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA.
- chr11:113,974,881–114,707,069, 18 genes: HTR3A, ZBTB16, AP002755.1, AP002518.2, NNMT, AP002518.1, C11orf71, RBM7, AP002373.1, REXO2, AP002373.2, NXPE2P1, AC020549.3, NXPE1, AC020549.1, NXPE4, AC020549.2, NXPE2.
- chr16:59,088,837–61,055,964, 14 genes: RPS27P27, AC092121.1, RNU4-58P, DUXAP11, APOOP5, LINC02141, AC009094.1, AC009081.2, AC018554.1, NPAP1L, AC009081.1, GNPATP, AC009169.1, RPS27AP16.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,340,998, 15 genes, copy number 5: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes, copy number 5: TRGV5P, TRGV5.

Autosomal genes at a single copy (total copy number 1): 1,720. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
